Surgical pathology report (de-identified scan), TCGA case TCGA-HU-8243, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-8243-01A (Primary Tumor).

Stomach, subtotal gastrectomy:

Advanced gastric carcinoma

(Muc2(-)/Muc5AC(+)/Muc6(-)/CD10(-)/cERB2(-):G type)

1. Location : middle third, Center at lower body, lesser curvature
2. Gross type : Borrmann type 2
3. Histologic type : Adenocarcinoma, tubular moderately differentiated (65%)
+ papillary type (20%) + micropapillary type (15%)
4. Histologic type by Lauren : intestinal
5. Growth pattern: mixed expanding and infiltrative growth pattern
6. Size : 9.4x8.0cm
7. Depth of invasion : invades serosa (pT4a)
8. Resection margin :
proximal margin – involvement by lymphatic emboli
distal margin – free from carcinoma
safety margin: 5.5cm
9. Lymph node metastasis : metastasis to 57 out of 81 regional lymph nodes (pN3b)
(lesser curvature 50/55, greater curvature 7/26)
10. Lymphatic invasion : present, marked
11. Venous invasion : present, marked
12. Perineural invasion : present, moderate
13. Separate lesion :
Tubular adenoma, high grade dysplasia, adenomatous type, gross type 0-I,
1) location : pylorus
2) size: 5.5x3.0cm
3) clear resection margin.

Specimen labeled as "anvil ring", biopsy:

No tumor.

Small intestine, jejunum, biopsy:

No tumor.

Immunohistochemistry : CD10, MUC2, MUC5ac, MUC6, C-erb B2

Source: NCI Genomic Data Commons file 2d19d3be-4082-410c-a3e6-cf57f5e14100 (TCGA-HU-8243.E7F6B603-F667-45ED-B2B0-79F5DB6D50C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).